Somatic mutation profile of tumor specimen TCGA-EJ-A46G-01A (aliquot TCGA-EJ-A46G-01A-31D-A26M-08) from TCGA case TCGA-EJ-A46G, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.8 years (26,219 days).
Specimen TCGA-EJ-A46G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd172e86-487e-4ac2-9ef3-af9e70202c75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A46G-10A (Blood Derived Normal), aliquot TCGA-EJ-A46G-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7b756ad-f3ab-4e00-a500-75488f5b7499

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 16, Nonsense Mutation 4, 3'UTR 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF1 | c.1466A>T p.N489I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV51945274; called by muse, mutect2, varscan2
- ATP10D | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV56703211, COSV56707021; called by muse, mutect2, varscan2
- B4GALT6 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV52703398; called by muse, mutect2, varscan2
- CDK12 | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71000495; called by muse, mutect2, varscan2
- CHRNA6 | c.1202C>A p.S401* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV52379393; called by muse, mutect2, varscan2
- CKMT2 | c.914T>C p.F305S | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54173077; called by muse, mutect2, varscan2
- CLEC12B | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1214988301, COSV58863310; called by muse, mutect2, varscan2
- EPB41L2 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61355004; called by muse, mutect2, varscan2
- FREM2 | c.8545-1G>T p.X2849_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as COSV54836394; called by muse, mutect2
- IFT122 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56202633, COSV99959668; called by muse, mutect2
- IRS1 | c.992A>T p.D331V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59335990; called by muse, mutect2, varscan2
- KEAP1 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs780969499, COSV50279167; called by muse, mutect2
- KPNA5 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs752133060, COSV62651472, COSV62652284; called by muse, mutect2, varscan2
- KPNB1 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV51596727, COSV51596840; called by muse, mutect2
- KRT79 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200262123; called by muse, mutect2, varscan2
- LRIG3 | c.1040T>G p.V347G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV57863217; called by muse, mutect2, varscan2
- LRRC15 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as COSV100752643, COSV61649991; called by muse, mutect2, varscan2
- MGAT5B | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778134396, COSV56927574; called by muse, mutect2, varscan2
- MMP26 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56172144; called by muse, mutect2, varscan2
- OR1K1 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757909265, COSV52956476; called by muse, mutect2, varscan2
- OR4C13 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101634151, COSV73648735; called by muse, mutect2, varscan2
- OR52A5 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV56615063; called by muse, mutect2, varscan2
- PCNX4 | c.170T>G p.V57G | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV58303794; called by muse, mutect2
- PLEKHG3 | c.2455C>T p.R819C (on ENST00000394691; = p.R875C on NM_001308147.2) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); catalogued as rs567652301, COSV55979722; called by muse, mutect2, varscan2
- PRKDC | c.11713G>A p.A3905T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs762000221, COSV58050874; called by muse, mutect2, varscan2
- SESN1 | c.334T>G p.L112V (on ENST00000356644 / NM_001199933.1; = p.L171V on NM_014454.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57420721; called by muse, mutect2, varscan2
- SPANXN1 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV65122342, COSV65123446; called by muse, mutect2
- SPTBN2 | c.3832C>T p.R1278W | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs373743022, COSV59451425; called by muse, mutect2, varscan2
- TMEM92 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs143844371; called by muse, mutect2, varscan2
- TRAIP | c.373T>A p.L125M | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58914202; called by muse, mutect2, varscan2
- UBXN10 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV66772123; called by muse, mutect2, varscan2
- USH2A | c.1853A>T p.E618V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56363299; called by muse, mutect2, varscan2
- VANGL2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760434234, COSV63604390; called by muse, mutect2, varscan2
- VHL | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56549420, COSV56565951; called by muse, mutect2, varscan2
- YJU2 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV53606105; called by muse, mutect2
- ZNF223 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.101); catalogued as COSV71571877; called by muse, mutect2, varscan2
- ZNF668 | c.1627C>A p.P543T | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56213884; called by muse, mutect2, varscan2
- ZSCAN10 | c.248C>T p.A83V (on ENST00000252463; = p.A138V on NM_032805.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs763114979, COSV52967844; called by muse, mutect2, varscan2
- CDK12 | c.1025dup p.S343Efs*8 | Frame Shift Ins (INS) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- NUDT12 | c.1174del p.M392Cfs*5 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- PRRC2A | c.1908C>A p.Y636* | Nonsense Mutation (SNP) | VAF 9/179 reads (5%) | called by muse, mutect2
- ABCC4 | c.1086G>A p.R362= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ADCY8 | c.819C>T p.Y273= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs752877479, COSV53905939; called by muse, mutect2, varscan2
- COL3A1 | c.1329C>T p.P443= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs527291598, COSV58586987; called by muse, mutect2, varscan2
- COL6A6 | c.1041C>T p.N347= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as rs372078727, COSV100650786; called by muse, mutect2
- DIDO1 | c.2877C>T p.T959= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs758805609, COSV56621086; called by muse, mutect2, varscan2
- MSL2 | c.66C>A p.P22= | Silent (SNP) | VAF 78/230 reads (34%) | catalogued as COSV59442439; called by muse, mutect2, varscan2
- MYLIP | c.1272T>A p.R424= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV62766674; called by muse, mutect2
- NUP210 | c.2823G>A p.R941= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV54405884, COSV54406392; called by muse, mutect2
- OR52M1 | c.579C>T p.G193= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs377446192; called by muse, mutect2, varscan2
- SSH3 | c.441G>T p.L147= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV57384633; called by muse, mutect2, varscan2
- TANC1 | c.2820C>T p.C940= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs201860716, COSV55087227; called by muse, mutect2, varscan2
- TAS1R1 | c.783C>T p.R261= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100062991; called by mutect2, varscan2
- TMEM205 | c.370C>A p.R124= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV55791382, COSV55793130; called by muse, mutect2, varscan2
- TTN | c.97326A>G p.K32442= (on ENST00000591111; = p.K25018= on NM_003319.4) | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV60023835; called by muse, mutect2, varscan2
- VANGL2 | c.1233G>A p.Q411= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV63604396; called by muse, mutect2, varscan2
- ZFHX4 | c.1254C>A p.T418= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV50733530; called by muse, mutect2, varscan2
- LEKR1 | c.*1050C>G | 3'UTR (SNP) | VAF 12/26 reads (46%) | catalogued as COSV62961715; called by muse, mutect2, varscan2
